TARGET case TARGET-10-PARVBS — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c1a67ba1-1027-550a-90a5-6b99b2b90912

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 16 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 16.3 years (5,947 days); Year of diagnosis: 2008; Days to last follow up: 52 days.
   Treatment given: Protocol identifier: AALL0232.

Follow-up (2 entries)
- Days to follow up: 34 days; Days to first event: 34 days; First event: Induction Failure.
- Days to follow up: 52 days; Year of follow up: 2008.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 7 ×10³/µL.
- Day 8: Bone Marrow blast count 80%; Minimal Residual Disease (Flow Cytometry) 1%.
- Day 15: Bone Marrow blast count 70%.
- Day 29: Bone Marrow blast count 72%; Minimal Residual Disease (Flow Cytometry) 86.2%.

Biospecimens (2 samples)
- Sample TARGET-10-PARVBS-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PARVBS-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 52
- WBC at Diagnosis: 7
- CNS Status at Diagnosis: CNS 2
- Testicular Involvement: No
- MRD Day 8: 1
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 86.2
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 80
- BMA Blasts Day 15: 70
- BMA Blasts Day 29: 72
- Karyotype: 46,XY,t(1;9)(p22;p13)[7]/46,XY[15]
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: None of the above
